Somatic mutation profile of cancer-model specimen HCM-BROD-0834-C43-85M (Adherent Cell Line, passage 9; aliquot HCM-BROD-0834-C43-85M-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-BROD-0834-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 78.9 years (28,828 days).
Specimen HCM-BROD-0834-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 934be603-a63c-470f-9fcd-b9636409a69d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0834-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0834-C43-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0064e12a-1660-46df-957d-1b191c95a1ae

The open-access MAF lists 1,238 somatic variants for this specimen: 783 protein-altering or splice-affecting, 412 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 713, Silent 412, Nonsense Mutation 46, Intron 29, Splice Region 11, Splice Site 7, Frame Shift Del 5, 3'UTR 4, RNA 4, 3'Flank 3, 5'UTR 2, 5'Flank 1.

Variants (750 of 1,238; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCK | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 376/763 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1064793134, CM096919; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LMBRD1 | c.1222C>T p.R408* (on ENST00000649011; = p.R386* on NM_018368.4) | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as rs1380343985, COSV65296997; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 159/333 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4811G>A p.W1604* (on ENST00000303395 / NM_001202435.3; = p.W1593* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 159/369 reads (43%) | catalogued as rs794726800, CM1511236, COSV57668685; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 183/401 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV55289954; called by muse, mutect2, varscan2
- ABCA5 | c.4315C>T p.R1439* | Nonsense Mutation (SNP) | VAF 77/171 reads (45%) | catalogued as rs372523620; called by muse, mutect2, varscan2
- ABCB5 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 150/314 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.386); catalogued as COSV51702673; called by muse, varscan2
- ABCC6 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 335/701 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52741958; called by muse, mutect2, varscan2
- ABHD16A | c.598G>C p.V200L | Missense Mutation (SNP) | VAF 261/752 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.033); catalogued as rs780830489; called by muse, mutect2, varscan2
- ABL2 | c.1342C>T p.P448S (on ENST00000502732 / NM_007314.4; = p.P433S on NM_005158.5) | Missense Mutation (SNP) | VAF 181/429 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs866780586, COSV61018642; called by muse, mutect2, varscan2
- ABLIM3 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 195/388 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs1197850966; called by muse, mutect2, varscan2
- ACE | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 214/432 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs371544905, COSV99327658; called by muse, mutect2, varscan2
- ACOD1 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 179/382 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); catalogued as rs1426756618; called by muse, varscan2
- ACTA2 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 160/349 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.926); catalogued as rs794728027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM18 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1228838970; called by muse, mutect2, varscan2
- ADAM18 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 218/435 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as rs865959777, COSV55845424; called by muse, mutect2, varscan2
- ADAM21 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 123/255 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99960599; called by muse, mutect2, varscan2
- ADAM7 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 214/472 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.399); catalogued as COSV51536126; called by muse, mutect2, varscan2
- ADAMTS13 | c.1437G>A p.G479= | Splice Region (SNP) | VAF 140/301 reads (47%) | catalogued as rs372953477, COSV63021506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS18 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 164/391 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51406470; called by muse, mutect2, varscan2
- ADAMTS18 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 188/389 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as COSV51420155; called by muse, mutect2, varscan2
- ADAMTS6 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 231/435 reads (53%) | SIFT tolerated (0.82); PolyPhen benign (0.363); catalogued as rs574046720, COSV58681823; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 217/419 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1447211714; called by muse, mutect2, varscan2
- ADCY4 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 136/277 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs777010278, COSV60252172; called by muse, mutect2, varscan2
- ADCY6 | c.2417C>T p.T806I | Missense Mutation (SNP) | VAF 177/411 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs1226659148, COSV57168411; called by muse, mutect2, varscan2
- ADCY8 | c.2302C>T p.P768S | Missense Mutation (SNP) | VAF 233/1121 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.433); catalogued as rs767845939; called by muse, mutect2, varscan2
- ADD2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 174/426 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.119); catalogued as COSV52454100; called by muse, mutect2, varscan2
- ADGRF5 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 169/356 reads (47%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.735); catalogued as COSV51930822; called by muse, mutect2, varscan2
- ADH1B | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 208/477 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59295195; called by muse, mutect2, varscan2
- ADRA1D | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 306/679 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1336684987, COSV65240762; called by muse, mutect2, varscan2
- AFF2 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 325/325 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.239); catalogued as COSV53981943, COSV53983499; called by muse, mutect2, varscan2
- AGT | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 245/494 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs753775475; called by muse, mutect2, varscan2
- AHR | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 128/279 reads (46%) | catalogued as rs925497930; called by muse, mutect2, varscan2
- AICDA | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 224/495 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386378825; called by muse, mutect2, varscan2
- AKAP9 | c.8119G>A p.E2707K (on ENST00000359028; = p.E2683K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/207 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV62337878; called by muse, mutect2, varscan2
- AKAP9 | c.11066C>T p.S3689F (on ENST00000359028; = p.S3665F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 156/333 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62340221; called by muse, mutect2, varscan2
- AKR1C2 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 94/261 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1554771957; called by muse, mutect2, varscan2
- ALB | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 119/255 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV55735785; called by muse, mutect2, varscan2
- ALDOB | c.544G>C p.G182R | Missense Mutation (SNP) | VAF 83/188 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.918); catalogued as COSV66397291; called by muse, mutect2, varscan2
- ALOX15 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 221/221 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs756674821; called by muse, mutect2, varscan2
- ALPK2 | c.5236G>A p.E1746K | Missense Mutation (SNP) | VAF 176/338 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV100864934; called by muse, mutect2, varscan2
- AMY1C | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as COSV100915196; called by muse, mutect2, varscan2
- AMY2A | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 87/357 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs768370675; called by muse, mutect2, varscan2
- AMY2B | c.391G>T p.G131* | Nonsense Mutation (SNP) | VAF 196/406 reads (48%) | catalogued as COSV100796442; called by muse, mutect2, varscan2
- ANKRD30B | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 187/382 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.801); catalogued as COSV62820400; called by muse, mutect2, varscan2
- ANKZF1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 258/542 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs376658598; called by muse, mutect2, varscan2
- ANO2 | c.2302C>T p.L768F (on ENST00000356134 / NM_001278597.3; = p.L772F on NM_001278596.3) | Missense Mutation (SNP) | VAF 246/491 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs765505051; called by muse, mutect2, varscan2
- AP4E1 | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 122/261 reads (47%) | catalogued as COSV55917161; called by muse, mutect2, varscan2
- APOB | c.4522G>A p.D1508N | Missense Mutation (SNP) | VAF 216/428 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.112); catalogued as COSV51941751; called by muse, mutect2, varscan2
- ARMC4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 202/413 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as rs866196713, COSV59455677; called by muse, mutect2, varscan2
- ATG4C | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 112/238 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100508614; called by muse, mutect2, varscan2
- ATP13A4 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 93/225 reads (41%) | catalogued as rs1472108737; called by muse, mutect2, varscan2
- ATXN1 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 541/823 reads (66%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs758093377, COSV55209499; called by muse, mutect2, varscan2
- AUTS2 | c.3331G>A p.E1111K | Missense Mutation (SNP) | VAF 310/660 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1384336956; called by muse, mutect2, varscan2
- BAIAP3 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 180/363 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100181502; called by muse, varscan2
- BAP1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 203/398 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV56236805, COSV99964448; called by muse, mutect2, varscan2
- BCAS3 | c.2435G>A p.R812Q (on ENST00000390652 / NM_001353144.2; = p.R797Q on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/381 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs1396862585, COSV101174905; called by muse, mutect2, varscan2
- BCAT1 | c.675G>A p.G225= | Splice Region (SNP) | VAF 122/252 reads (48%) | catalogued as COSV53910615; called by muse, mutect2, varscan2
- BNIP5 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 117/403 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs750479175, COSV71325403; called by muse, mutect2, varscan2
- C12orf42 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as rs773446119, COSV59378762; called by muse, mutect2, varscan2
- C16orf54 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 352/701 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); catalogued as COSV61477125; called by muse, mutect2, varscan2
- C16orf90 | c.509G>A p.G170E (on ENST00000399645 / NM_001353385.2; = p.G161E on NM_001080524.2) | Missense Mutation (SNP) | VAF 179/420 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.027); catalogued as COSV101290966; called by muse, mutect2, varscan2
- C16orf92 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 162/330 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1489209519; called by muse, mutect2, varscan2
- CATSPERE | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 150/331 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1008364869; called by muse, mutect2, varscan2
- CBLL1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 196/401 reads (49%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.658); catalogued as rs1207309123; called by muse, mutect2, varscan2
- CBLN3 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 276/558 reads (49%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs375714567; called by muse, mutect2, varscan2
- CCDC141 | c.4300G>A p.G1434R | Missense Mutation (SNP) | VAF 101/221 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55372398, COSV99836852; called by muse, mutect2, varscan2
- CCDC38 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 190/421 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780190657, COSV60183805; called by muse, mutect2, varscan2
- CCDC73 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58795949; called by muse, mutect2, varscan2
- CD163 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 222/402 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs867643659, COSV63135418; called by muse, mutect2, varscan2
- CD163 | c.1736-8C>T | Splice Region (SNP) | VAF 233/494 reads (47%) | catalogued as COSV63129888; called by muse, mutect2, varscan2
- CD163 | c.885G>A p.W295* | Nonsense Mutation (SNP) | VAF 154/379 reads (41%) | catalogued as rs750240390; called by muse, mutect2, varscan2
- CDH9 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 89/168 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.074); catalogued as COSV50267939, COSV50312263; called by muse, mutect2, varscan2
- CDYL2 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 208/430 reads (48%) | catalogued as rs1455559785, COSV73647513; called by muse, mutect2
- CELSR2 | c.6064C>T p.L2022F | Missense Mutation (SNP) | VAF 227/463 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772338483; called by muse, mutect2, varscan2
- CFAP20DC | c.602G>A p.R201Q (on ENST00000482387 / NM_001351530.2; = p.R76Q on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 158/313 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as rs778956286, COSV55924982; called by muse, mutect2, varscan2
- CFAP47 | c.5099G>A p.W1700* | Nonsense Mutation (SNP) | VAF 73/73 reads (100%) | catalogued as COSV57973974; called by muse, mutect2, varscan2
- CFAP54 | c.4414C>T p.R1472C | Missense Mutation (SNP) | VAF 127/307 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs1385646460, COSV61573182; called by muse, mutect2, varscan2
- CFAP54 | c.8686C>T p.R2896C | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs775459138; called by muse, mutect2, varscan2
- CHD8 | c.1972C>T p.P658S (on ENST00000646647 / NM_001170629.2; = p.P379S on NM_020920.4) | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs201662166, COSV67870298; called by muse, mutect2, varscan2
- CHST5 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 288/678 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs769120794, COSV60340043; called by muse, mutect2, varscan2
- CILP2 | c.2468C>T p.S823F | Missense Mutation (SNP) | VAF 317/656 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866357495; called by muse, mutect2, varscan2
- CLCA1 | c.1650G>A p.M550I | Missense Mutation (SNP) | VAF 114/279 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.113); catalogued as COSV52329141; called by muse, mutect2, varscan2
- CLEC14A | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 318/611 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs113776316; called by muse, mutect2, varscan2
- CNTN4 | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 137/298 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV61880694; called by muse, mutect2, varscan2
- CNTNAP3 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 269/298 reads (90%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs373851232, COSV99034462; called by muse, mutect2, varscan2
- COL11A1 | c.5069C>T p.S1690F | Missense Mutation (SNP) | VAF 109/239 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV62199099, COSV62200534; called by muse, mutect2, varscan2
- COL16A1 | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 172/369 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54711727; called by muse, mutect2, varscan2
- COL21A1 | c.2020G>A p.G674R | Missense Mutation (SNP) | VAF 120/270 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55179809; called by muse, mutect2, varscan2
- COL6A5 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 177/398 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55213024; called by muse, mutect2, varscan2
- CORO7 | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 285/587 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1163895377, COSV52029185; called by muse, mutect2, varscan2
- CPB1 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 159/351 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as rs751218745; called by muse, mutect2, varscan2
- CPSF4 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 201/482 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV52853780; called by muse, mutect2, varscan2
- CRYBG2 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 304/676 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1557715683; called by muse, mutect2
- CSF3R | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 166/297 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV100118120, COSV58969124; called by muse, varscan2
- CSF3R | c.1431G>A p.W477* | Nonsense Mutation (SNP) | VAF 190/409 reads (46%) | catalogued as COSV100117111; called by muse, varscan2
- CSMD3 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 185/929 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52164534; called by muse, mutect2, varscan2
- CSNKA2IP | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 157/327 reads (48%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.001); catalogued as rs1332778015; called by muse, mutect2, varscan2
- CUL7 | c.4111G>A p.E1371K | Missense Mutation (SNP) | VAF 266/566 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as CD1210391; called by muse, mutect2, varscan2
- CYFIP2 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 156/317 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as COSV59050054; called by muse, mutect2, varscan2
- CYP11A1 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 111/234 reads (47%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.938); catalogued as rs867506250; called by muse, mutect2, varscan2
- CYP2J2 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 191/388 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs746763403; called by muse, mutect2, varscan2
- CYP4A11 | c.1287+1G>A p.X429_splice | Splice Site (SNP) | VAF 149/322 reads (46%) | catalogued as rs186780775; called by muse, mutect2, varscan2
- CYP4Z1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.698); catalogued as rs762956296; called by muse, mutect2, varscan2
- DBR1 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 181/374 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53430865; called by muse, mutect2, varscan2
- DCAF11 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 192/391 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV58108520; called by muse, mutect2, varscan2
- DCC | c.2954C>A p.T985N | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59129228; called by muse, mutect2, varscan2
- DCC | c.3393G>A p.K1131= | Splice Region (SNP) | VAF 147/281 reads (52%) | catalogued as COSV71427284; called by muse, mutect2, varscan2
- DCDC2B | c.851-1G>A p.X284_splice | Splice Site (SNP) | VAF 120/275 reads (44%) | catalogued as rs747754033; called by muse, mutect2
- DCLK2 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 204/393 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56198740; called by muse, mutect2, varscan2
- DDAH1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 113/250 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.392); catalogued as rs763875537; called by muse, mutect2, varscan2
- DDX60L | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 172/405 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202002269; called by muse, mutect2, varscan2
- DDX60L | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 145/333 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs761894325, COSV52716696; called by muse, mutect2, varscan2
- DGKI | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 116/233 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99932427; called by muse, mutect2, varscan2
- DGKK | c.1847G>A p.W616* | Nonsense Mutation (SNP) | VAF 141/141 reads (100%) | catalogued as COSV101053081, COSV65709104; called by muse, mutect2, varscan2
- DISP3 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 215/455 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53822416; called by muse, mutect2, varscan2
- DIXDC1 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 101/101 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782795876, COSV101098127; called by muse, mutect2, varscan2
- DLG2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 190/384 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV101074484, COSV65860536; called by muse, mutect2, varscan2
- DMTN | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 223/507 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs146615047; called by muse, mutect2, varscan2
- DNAH10 | c.4384G>A p.E1462K (on ENST00000409039; = p.E1401K on NM_207437.3) | Missense Mutation (SNP) | VAF 135/305 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.377); catalogued as COSV68992147; called by muse, mutect2, varscan2
- DNAH7 | c.6736C>T p.H2246Y | Missense Mutation (SNP) | VAF 173/358 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1361587243, COSV56751994; called by muse, mutect2, varscan2
- DNAI3 | c.1138C>T p.L380F | Missense Mutation (SNP) | VAF 161/311 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54000284; called by muse, mutect2, varscan2
- DNAJC10 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.108); catalogued as rs775504249; called by muse, mutect2, varscan2
- DNER | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 324/630 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1189801764; called by muse, varscan2
- DNHD1 | c.3100G>A p.E1034K | Missense Mutation (SNP) | VAF 119/419 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1264126515, COSV99600608; called by muse, mutect2, varscan2
- DOK6 | c.290-1G>A p.X97_splice | Splice Site (SNP) | VAF 92/176 reads (52%) | catalogued as rs1191838037, COSV66929858; called by muse, varscan2
- DPP10 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 132/276 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs147078556; called by muse, mutect2, varscan2
- DPP10 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1209458494, COSV59726814; called by muse, mutect2, varscan2
- DSCAM | c.4315G>A p.E1439K | Missense Mutation (SNP) | VAF 216/433 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV68020915; called by muse, mutect2, varscan2
- DSTYK | c.2443C>T p.H815Y | Missense Mutation (SNP) | VAF 149/308 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs868788895, COSV65688701; called by muse, mutect2, varscan2
- ECD | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 109/243 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs1564664337; called by muse, mutect2, varscan2
- EMILIN2 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 209/399 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as COSV54426770; called by muse, mutect2, varscan2
- EPB41L2 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 152/294 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61356999; called by muse, mutect2, varscan2
- EPHA6 | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 187/368 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761842720; called by muse, mutect2, varscan2
- EPS8L3 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 164/334 reads (49%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100719756; called by mutect2, varscan2
- ERBB4 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 106/248 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.858); catalogued as COSV53522603, COSV53585586; called by muse, mutect2, varscan2
- ERICH3 | c.4088C>T p.S1363L | Missense Mutation (SNP) | VAF 230/450 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751032690, COSV58619044; called by muse, mutect2, varscan2
- ERVV-1 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 133/546 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs774584851; called by muse, mutect2, varscan2
- ERVW-1 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 224/481 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.389); catalogued as rs1335678481; called by muse, mutect2, varscan2
- EYA1 | c.981G>A p.W327* | Nonsense Mutation (SNP) | VAF 115/370 reads (31%) | catalogued as COSV58168918; called by muse, mutect2, varscan2
- F13A1 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 192/662 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV53562948; called by muse, mutect2, varscan2
- F7 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 316/633 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs550074221, CM090305, COSV60645310; called by muse, mutect2
- FAM135B | c.3677C>T p.S1226L | Missense Mutation (SNP) | VAF 171/869 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs780775718, COSV52702552; called by muse, mutect2, varscan2
- FAM83C | c.1936G>A p.G646S | Missense Mutation (SNP) | VAF 276/559 reads (49%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV65582138; called by muse, mutect2, varscan2
- FAT2 | c.10388C>T p.S3463L | Missense Mutation (SNP) | VAF 222/479 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.647); catalogued as rs758888520, COSV55817482; called by muse, mutect2, varscan2
- FAT3 | c.3259G>A p.G1087S | Missense Mutation (SNP) | VAF 125/236 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1261815109, COSV53109800; called by muse, mutect2, varscan2
- FBN2 | c.2470G>A p.G824R | Missense Mutation (SNP) | VAF 117/270 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199733916; called by muse, mutect2, varscan2
- FBXO40 | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 186/403 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57527958; called by muse, mutect2, varscan2
- FLNB | c.7556G>A p.G2519E | Missense Mutation (SNP) | VAF 172/358 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308690935; called by muse, varscan2
- FREM1 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 827/1049 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV101085369; called by muse, mutect2, varscan2
- GALNT13 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 157/361 reads (43%) | catalogued as rs1018857509, COSV67217164; called by muse, mutect2, varscan2
- GDF6 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 272/1499 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1423852021; called by muse, mutect2, varscan2
- GIMAP6 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 117/259 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100188092; called by muse, mutect2, varscan2
- GJB2 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 265/524 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs104894403, CM109516, CM990690, COSV101241478; called by muse, mutect2, varscan2
- GLDN | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 116/256 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59091151; called by muse, mutect2, varscan2
- GPATCH8 | c.3079C>T p.R1027C | Missense Mutation (SNP) | VAF 191/417 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1005554315, COSV100132835; called by muse, mutect2, varscan2
- GPR50 | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 268/268 reads (100%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.033); catalogued as rs765410234; called by muse, mutect2, varscan2
- GRIN2A | c.3544G>A p.D1182N | Missense Mutation (SNP) | VAF 207/397 reads (52%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.747); catalogued as rs375160358, COSV58030043; called by muse, mutect2, varscan2
- GRM3 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 163/375 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64468191; called by muse, mutect2, varscan2
- GRM4 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 183/579 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.412); catalogued as rs750684981, COSV65211964; called by muse, mutect2, varscan2
- GRM7 | c.2214G>A p.M738I | Missense Mutation (SNP) | VAF 224/459 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV63161836; called by muse, mutect2
- GRM8 | c.1429C>T p.Q477* | Nonsense Mutation (SNP) | VAF 166/348 reads (48%) | catalogued as rs1371651940; called by muse, mutect2, varscan2
- GRXCR1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 158/360 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV67670833; called by muse, mutect2, varscan2
- GYS2 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 178/385 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1230733508; called by muse, mutect2, varscan2
- GZMB | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 212/399 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as rs969918445; called by muse, mutect2, varscan2
- HCN1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 116/223 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57502899; called by muse, mutect2, varscan2
- HDAC1 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 162/343 reads (47%) | catalogued as COSV61482340; called by muse, mutect2, varscan2
- HEPACAM2 | c.1007C>T p.S336F (on ENST00000394468 / NM_001039372.4; = p.S324F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/197 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV59060154; called by muse, mutect2, varscan2
- HFM1 | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54037359; called by muse, mutect2, varscan2
- HIVEP2 | c.2177C>T p.S726F | Missense Mutation (SNP) | VAF 235/235 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs754278327, COSV50031237; called by muse, mutect2, varscan2
- HLCS | c.2023C>T p.H675Y | Missense Mutation (SNP) | VAF 162/339 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs368743397; called by muse, mutect2, varscan2
- HRNR | c.5785G>A p.G1929S | Missense Mutation (SNP) | VAF 228/4652 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.078); catalogued as rs774710231; called by muse, mutect2
- HYDIN | c.11830C>T p.R3944W | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1353096518, COSV66638801; called by muse, mutect2, varscan2
- ICE2 | c.2606C>T p.S869F | Missense Mutation (SNP) | VAF 120/245 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55030727; called by muse, mutect2, varscan2
- IL36RN | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 199/448 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100697301, COSV61010445; called by muse, mutect2, varscan2
- IL37 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 163/351 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54490299; called by muse, mutect2, varscan2
- IL7R | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 278/540 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.275); catalogued as COSV57407340; called by muse, mutect2, varscan2
- INF2 | c.3271C>T p.P1091S | Missense Mutation (SNP) | VAF 262/526 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs376315431; called by muse, mutect2, varscan2
- IQGAP2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 132/304 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs766715473, COSV57172166; called by muse, mutect2, varscan2
- IRF2BPL | c.2107C>T p.P703S | Missense Mutation (SNP) | VAF 280/585 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.667); catalogued as rs369742014; called by muse, mutect2, varscan2
- ITGA3 | c.1078C>T p.L360F | Missense Mutation (SNP) | VAF 244/501 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); catalogued as COSV99144008; called by muse, mutect2, varscan2
- IVL | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 207/462 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.351); catalogued as COSV100908099, COSV64216367; called by muse, mutect2
- JAK3 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 175/356 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as rs1323968278; called by muse, mutect2, varscan2
- JRKL | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 118/250 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs1391241792; called by muse, mutect2, varscan2
- JUP | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 165/339 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1321508670; called by muse, mutect2, varscan2
- KCNB2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 467/591 reads (79%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.96); catalogued as COSV73049036; called by muse, mutect2, varscan2
- KCNQ3 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 521/674 reads (77%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV66475740; called by muse, mutect2, varscan2
- KDM3A | c.1787A>G p.D596G | Missense Mutation (SNP) | VAF 141/308 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as COSV100461039; called by muse, mutect2, varscan2
- KIF11 | c.3014C>T p.S1005L | Missense Mutation (SNP) | VAF 127/271 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs776614086, COSV53270028; called by muse, mutect2, varscan2
- KLK10 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 293/620 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs761167574; called by muse, mutect2, varscan2
- KLRD1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 104/232 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs781608711, COSV60273338, COSV60274015; called by muse, mutect2, varscan2
- KMT2B | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 358/726 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs773749210; called by muse, mutect2, varscan2
- KRT1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 127/261 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99078880; called by muse, mutect2, varscan2
- KRT84 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 278/528 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs747946695, COSV57770506; called by muse, mutect2
- LDHAL6B | c.828G>A p.W276* | Nonsense Mutation (SNP) | VAF 157/282 reads (56%) | catalogued as COSV55686597; called by muse, mutect2, varscan2
- LEPR | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV60748527; called by muse, mutect2, varscan2
- LGR4 | c.1784C>T p.T595I | Missense Mutation (SNP) | VAF 180/361 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369900849; called by muse, mutect2, varscan2
- LGR6 | c.2549C>T p.P850L (on ENST00000367278 / NM_001017403.1; = p.P798L on NM_021636.3) | Missense Mutation (SNP) | VAF 240/569 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV55166852; called by muse, mutect2, varscan2
- LILRA1 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs759386874, COSV52177919; called by muse, mutect2
- LILRB1 | c.199C>T p.L67F (on ENST00000427581; = p.L31F on NM_006669.6) | Missense Mutation (SNP) | VAF 117/363 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as rs777936405, COSV61118496; called by muse, mutect2, varscan2
- LPA | c.4333C>T p.R1445C | Missense Mutation (SNP) | VAF 374/547 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs778266525, COSV60300378; called by muse, mutect2, varscan2
- LPAR3 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 241/488 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV65453746; called by muse, mutect2, varscan2
- LRRN4 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 282/533 reads (53%) | SIFT tolerated (0.89); PolyPhen benign (0.026); catalogued as COSV101125425, COSV66645711; called by muse, mutect2, varscan2
- LSM14A | c.1243C>T p.L415F | Missense Mutation (SNP) | VAF 279/617 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.034); catalogued as rs376476220, COSV70885139; called by muse, mutect2, varscan2
- LTK | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 291/641 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1424711608; called by muse, mutect2, varscan2
- MARCO | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 97/220 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.284); catalogued as rs771963608, COSV59056016; called by muse, mutect2, varscan2
- MARCO | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 156/310 reads (50%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.488); catalogued as COSV59052545; called by muse, mutect2, varscan2
- MDGA2 | c.2398C>T p.R800C (on ENST00000399232 / NM_001113498.2; = p.R502C on NM_182830.4) | Missense Mutation (SNP) | VAF 129/257 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776310493, COSV62078486; called by muse, mutect2, varscan2
- MECOM | c.1567C>T p.P523S (on ENST00000468789 / NM_001105078.4; = p.P711S on NM_004991.4) | Missense Mutation (SNP) | VAF 219/427 reads (51%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.996); catalogued as COSV52959454; called by muse, mutect2, varscan2
- MECOM | c.515C>T p.S172L (on ENST00000468789 / NM_001105078.4; = p.S360L on NM_004991.4) | Missense Mutation (SNP) | VAF 169/370 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748747672, COSV52959668; called by muse, mutect2, varscan2
- MGAM2 | c.3871G>A p.E1291K | Missense Mutation (SNP) | VAF 119/264 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV101522985; called by muse, mutect2, varscan2
- MMP24 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 210/477 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as COSV55770209; called by muse, mutect2, varscan2
- MMRN2 | c.2188C>T p.L730F | Missense Mutation (SNP) | VAF 287/547 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs1357673791; called by muse, mutect2, varscan2
- MNDA | c.572A>T p.N191I | Missense Mutation (SNP) | VAF 134/243 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1373560853; called by muse, mutect2, varscan2
- MTFR1 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200858272, COSV50951197; called by muse, mutect2, varscan2
- MTNR1A | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 88/172 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56155582; called by muse, mutect2, varscan2
- MUC16 | c.27706G>A p.E9236K | Missense Mutation (SNP) | VAF 166/371 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.069); catalogued as rs763596704; called by muse, mutect2, varscan2
- MUC16 | c.24178G>A p.D8060N | Missense Mutation (SNP) | VAF 210/443 reads (47%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.125); catalogued as rs541350099, COSV101198208; called by muse, mutect2, varscan2
- MUC16 | c.18184G>A p.E6062K | Missense Mutation (SNP) | VAF 220/445 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.192); catalogued as rs892618039; called by muse, mutect2, varscan2
- MUC16 | c.10097C>T p.S3366F | Missense Mutation (SNP) | VAF 171/371 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.757); catalogued as COSV67488011; called by muse, mutect2, varscan2
- MUC16 | c.7888C>T p.P2630S | Missense Mutation (SNP) | VAF 141/316 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV67476439; called by muse, mutect2, varscan2
- MUC16 | c.5513C>T p.A1838V | Missense Mutation (SNP) | VAF 192/425 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs752594278; called by muse, mutect2, varscan2
- MYBBP1A | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 261/261 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs763901169; called by muse, mutect2, varscan2
- MYH11 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 176/407 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV100259940; called by muse, mutect2, varscan2
- MYH15 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 126/272 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as rs750652915; called by muse, mutect2, varscan2
- MYL7 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 167/315 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs763245152; called by muse, mutect2, varscan2
- MYOM3 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 208/392 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs745583615, COSV100292700; called by muse, mutect2, varscan2
- NAA11 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 186/438 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs868363838, COSV54514672; called by muse, mutect2, varscan2
- NBL1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 121/232 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as COSV57029948; called by muse, mutect2, varscan2
- NCF4 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 189/371 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs900312893, COSV99957156; called by muse, mutect2, varscan2
- NCKAP5 | c.3209C>T p.P1070L | Missense Mutation (SNP) | VAF 208/430 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs1415935134; called by muse, mutect2, varscan2
- NCOR2 | c.3147G>A p.W1049* | Nonsense Mutation (SNP) | VAF 338/684 reads (49%) | catalogued as COSV62298184; called by muse, mutect2, varscan2
- NDNF | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 195/404 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs772379451, COSV65634725; called by muse, mutect2, varscan2
- NECTIN3 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 196/403 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs780559368, COSV60549749; called by muse, mutect2, varscan2
- NEXMIF | c.3871C>T p.P1291S | Missense Mutation (SNP) | VAF 306/306 reads (100%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs767020320, COSV50069769; called by muse, mutect2, varscan2
- NEXMIF | c.3200C>T p.S1067F | Missense Mutation (SNP) | VAF 252/252 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867424090, COSV50023304; called by muse, mutect2, varscan2
- NGDN | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 134/320 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1352006194; called by muse, mutect2, varscan2
- NLRP2 | c.3073G>A p.D1025N | Missense Mutation (SNP) | VAF 140/251 reads (56%) | SIFT tolerated (0.52); PolyPhen benign (0.274); catalogued as rs1467652508; called by muse, mutect2, varscan2
- NLRP8 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 173/337 reads (51%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.593); catalogued as rs142211286; called by muse, mutect2, varscan2
- NLRP8 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 142/335 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0.271); catalogued as COSV52593443; called by muse, mutect2, varscan2
- NLRP9 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 216/438 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs773656654, COSV60462226; called by muse, mutect2, varscan2
- NRXN1 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 226/507 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1312769037, COSV101280653; called by muse, mutect2, varscan2
- NUP160 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 162/347 reads (47%) | catalogued as COSV101021557; called by muse, mutect2, varscan2
- OCIAD1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 137/285 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1469980557; called by muse, mutect2, varscan2
- OPRD1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 211/449 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as rs780286580, COSV52382830; called by muse, mutect2, varscan2
- OPRL1 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 311/648 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs772654648; called by muse, mutect2, varscan2
- OPRPN | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 176/399 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV68192656; called by muse, mutect2, varscan2
- OR10G7 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 257/260 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs1253874078, COSV57866816; called by muse, mutect2, varscan2
- OR10G9 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 222/224 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as rs768083203, COSV66686101; called by muse, mutect2, varscan2
- OR10G9 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 220/222 reads (99%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV66686529; called by muse, mutect2, varscan2
- OR10J3 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 190/398 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.167); catalogued as rs919949948; called by muse, mutect2, varscan2
- OR13C4 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 173/375 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs75737900; called by muse, mutect2, varscan2
- OR14A2 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 200/422 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs1356882880; called by muse, mutect2
- OR1F1 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 150/321 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV58960347; called by muse, mutect2, varscan2
- OR2A2 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 189/393 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV68871596, COSV68871682; called by muse, mutect2, varscan2
- OR2A5 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 177/364 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs149614119, COSV68738535; called by muse, mutect2, varscan2
- OR2J3 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 561/864 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs754215512, COSV65849020, COSV65849371; called by muse, mutect2, varscan2
- OR2T12 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 200/404 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as rs267598501, COSV58777909; called by muse, mutect2, varscan2
- OR2T35 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 210/522 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs1386382144, COSV100442226; called by muse, mutect2, varscan2
- OR4K13 | c.812T>A p.L271H | Missense Mutation (SNP) | VAF 98/182 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867962405; called by muse, mutect2, varscan2
- OR4N2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 235/501 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV60050111; called by muse, mutect2, varscan2
- OR4Q2 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 179/378 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs983631004, COSV73406224; called by muse, mutect2, varscan2
- OR51A7 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 191/397 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs778988096, COSV100834717, COSV100834731; called by muse, mutect2, varscan2
- OR52E8 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 119/297 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs781170349, COSV66205287; called by muse, mutect2, varscan2
- OR52I2 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 227/469 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100443007; called by muse, mutect2, varscan2
- OR56A1 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 189/387 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV57362472; called by muse, mutect2, varscan2
- OR56A4 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 210/412 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs749332994; called by muse, mutect2
- OR5F1 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 187/422 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.711); catalogued as COSV99558538; called by muse, mutect2, varscan2
- OR5H14 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 113/317 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV71194162; called by muse, mutect2, varscan2
- OR5H6 | c.611C>T p.S204F (on ENST00000642105; = p.S188F on NM_001005479.2) | Missense Mutation (SNP) | VAF 79/188 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67351044; called by muse, mutect2
- OR6C1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 178/341 reads (52%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs867442232, COSV65572609; called by muse, mutect2, varscan2
- OR6C2 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 201/445 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV59515501; called by muse, mutect2, varscan2
- OR6C4 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 137/287 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV67793117; called by muse, mutect2, varscan2
- OR6F1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as rs866322456, COSV57469416; called by muse, mutect2, varscan2
- OR8H3 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 177/372 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs547287374, COSV57909356; called by muse, mutect2, varscan2
- OR8J1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 116/240 reads (48%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV57318071; called by muse, mutect2, varscan2
- OSMR | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 88/197 reads (45%) | catalogued as rs199844167; called by muse, varscan2
- OTUD7B | c.2399C>T p.T800I | Missense Mutation (SNP) | VAF 202/433 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.46); catalogued as rs782297708; called by muse, mutect2, varscan2
- PABPC4L | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 156/320 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs868469335, COSV69928983; called by muse, mutect2, varscan2
- PADI6 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 240/470 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs369382323; called by muse, mutect2, varscan2
- PAK5 | c.1607C>T p.T536I | Missense Mutation (SNP) | VAF 162/310 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760772824, COSV62026820; called by muse, mutect2, varscan2
- PAK5 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 186/371 reads (50%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV62030621; called by muse, mutect2, varscan2
- PALB2 | c.2849C>T p.S950F | Missense Mutation (SNP) | VAF 91/201 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs876659160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAPPA2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 201/442 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.968); catalogued as COSV62783896; called by muse, mutect2, varscan2
- PASK | c.2366C>T p.S789L | Missense Mutation (SNP) | VAF 291/563 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs753967050; called by muse, mutect2, varscan2
- PBX1 | c.1044G>A p.M348I | Missense Mutation (SNP) | VAF 163/355 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as rs761944828; called by muse, mutect2, varscan2
- PCDH15 | c.2002G>A p.G668R | Missense Mutation (SNP) | VAF 125/273 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1051206153, COSV57256966, COSV57278999, COSV57411195; called by muse, mutect2, varscan2
- PCDH15 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 202/414 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV57409812; called by muse, mutect2, varscan2
- PCDHA10 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 166/366 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs140022509, COSV56500580; called by muse, mutect2, varscan2
- PCDHA11 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 201/417 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.11); catalogued as rs1554164197, COSV56488954, COSV56544731; called by muse, mutect2, varscan2
- PCDHA3 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 307/626 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as rs149543626; called by muse, mutect2, varscan2
- PCDHB15 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 158/306 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51031199; called by muse, mutect2, varscan2
- PCDHB4 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 412/847 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs782064797, COSV52028091, COSV99521960; called by muse, mutect2, varscan2
- PCDHB7 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 260/1652 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV50760573; called by muse, mutect2
- PCDHB8 | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 414/2570 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.33); catalogued as COSV99177251; called by muse, mutect2, varscan2
- PCDHGA9 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 194/458 reads (42%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.014); catalogued as COSV53972957; called by muse, mutect2, varscan2
- PCED1B | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 168/364 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71395453; called by muse, mutect2, varscan2
- PCK1 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 144/290 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs757690926; called by muse, mutect2
- PCLO | c.5579C>T p.S1860L | Missense Mutation (SNP) | VAF 155/332 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61630354; called by muse, mutect2, varscan2
- PCLO | c.4367C>T p.S1456F | Missense Mutation (SNP) | VAF 149/312 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs779695259, COSV61653523; called by muse, mutect2, varscan2
- PHACTR2 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 92/92 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766664422, COSV99992576; called by muse, mutect2, varscan2
- PKD1L1 | c.5420G>A p.R1807Q | Missense Mutation (SNP) | VAF 138/336 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs771122484; called by muse, mutect2, varscan2
- PLAGL2 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 241/510 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.066); catalogued as rs1341397214, COSV55789344; called by muse, mutect2, varscan2
- PLCH2 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 189/401 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs753992333, COSV53951068; called by muse, mutect2, varscan2
- PLCZ1 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 144/330 reads (44%) | catalogued as rs745955620, COSV56854741; called by muse, mutect2, varscan2
- PLPPR1 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 252/501 reads (50%) | catalogued as COSV66457472; called by muse, mutect2, varscan2
- PLS1 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 101/228 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61833525; called by muse, mutect2, varscan2
- PLXDC1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 226/502 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV59554333; called by muse, mutect2, varscan2
- PLXNC1 | c.2113A>T p.K705* | Nonsense Mutation (SNP) | VAF 112/257 reads (44%) | catalogued as COSV51583617; called by muse, mutect2, varscan2
- PMFBP1 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 148/305 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV52829998; called by muse, mutect2, varscan2
- POLRMT | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 400/824 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs756790270; called by muse, mutect2, varscan2
- PPP4R4 | c.1730G>A p.G577E | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV58557843; called by muse, mutect2, varscan2
- PRDM13 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 263/263 reads (100%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.037); catalogued as rs1176630459; called by muse, mutect2, varscan2
- PRDM13 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 262/263 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.071); catalogued as rs1361020011; called by muse, mutect2, varscan2
- PRDM9 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 132/309 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs754142725, COSV57009588, COSV57012020; called by muse, mutect2, varscan2
- PROKR2 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 213/451 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs754872933; called by muse, mutect2, varscan2
- PRPF40B | c.1441C>T p.R481W (on ENST00000380281; = p.R475W on NM_012272.3) | Missense Mutation (SNP) | VAF 234/530 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs764686125, COSV56059152; called by muse, mutect2, varscan2
- PRRC2C | c.6890C>T p.S2297L (on ENST00000367742; = p.S2295L on NM_015172.4) | Missense Mutation (SNP) | VAF 190/388 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV58902730; called by muse, mutect2, varscan2
- PSG2 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 159/362 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as COSV61545145; called by muse, mutect2, varscan2
- PSG5 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV61654589; called by muse, mutect2, varscan2
- PSG6 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 202/501 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV51830662, COSV99413742; called by muse, mutect2, varscan2
- PSME3 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 190/423 reads (45%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.965); catalogued as rs751193290, COSV53198717; called by muse, mutect2, varscan2
- PTCHD3 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 247/428 reads (58%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV71256336; called by muse, mutect2, varscan2
- PTGIS | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 129/271 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773626394; called by muse, mutect2, varscan2
- PTPRD | c.2262G>A p.M754I | Missense Mutation (SNP) | VAF 192/192 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as COSV61939357, COSV61957177; called by muse, mutect2, varscan2
- RABGAP1L | c.1787G>A p.G596E | Missense Mutation (SNP) | VAF 122/231 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.439); catalogued as COSV52290841; called by muse, mutect2, varscan2
- RAD21 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 430/564 reads (76%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); catalogued as rs1337189031, COSV52056655; called by muse, mutect2, varscan2
- RASGRF2 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 156/351 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV54126640; called by muse, mutect2, varscan2
- RAX2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 295/565 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.274); catalogued as rs370757303, COSV100349520; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RBMXL2 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 232/483 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV60979835; called by muse, mutect2, varscan2
- RELN | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 141/318 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as COSV58991841; called by muse, mutect2, varscan2
- REXO1 | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 175/392 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV50076132; called by muse, varscan2
- RGPD3 | c.3773C>T p.A1258V | Missense Mutation (SNP) | VAF 271/550 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV58748035; called by muse, mutect2, varscan2
- RIN1 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 269/593 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs137954374; called by muse, mutect2, varscan2
- RNF6 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 146/336 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1315955619, COSV60417908; called by muse, mutect2, varscan2
- RPL28 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 251/512 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.447); catalogued as rs1320951324; called by muse, mutect2, varscan2
- RRAS2 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 126/228 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV56330154; called by muse, mutect2, varscan2
- RTF1 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 115/262 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV67479083; called by muse, mutect2, varscan2
- RXFP2 | c.1002G>A p.L334= | Splice Region (SNP) | VAF 98/172 reads (57%) | catalogued as rs200224877, COSV53634179; called by muse, mutect2, varscan2
- RYR1 | c.10792G>A p.E3598K | Missense Mutation (SNP) | VAF 214/463 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.551); catalogued as rs1322440459, COSV100616015; called by muse, mutect2, varscan2
- RYR3 | c.4722C>G p.S1574R | Missense Mutation (SNP) | VAF 219/503 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as rs1185351098, COSV101212473; called by muse, mutect2, varscan2
- SACS | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 247/496 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV66533644; called by muse, mutect2, varscan2
- SALL1 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 176/387 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs867169108, COSV51761481; called by muse, mutect2, varscan2
- SAPCD1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 403/652 reads (62%) | SIFT tolerated (0.74); PolyPhen benign (0.047); catalogued as rs1234866850, COSV100991938; called by muse, mutect2, varscan2
- SCN10A | c.5345G>A p.R1782Q | Missense Mutation (SNP) | VAF 248/509 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs267599796, COSV71860696; called by muse, mutect2
- SCN10A | c.3248C>T p.S1083F | Missense Mutation (SNP) | VAF 162/355 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as COSV101479444; called by muse, mutect2
- SCN11A | c.3607A>T p.K1203* | Nonsense Mutation (SNP) | VAF 150/340 reads (44%) | catalogued as rs1553633785; called by muse, mutect2, varscan2
- SENP7 | c.2950C>T p.P984S | Missense Mutation (SNP) | VAF 206/400 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288003232, COSV100052721; called by muse, mutect2, varscan2
- SERPINB13 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 185/378 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs376580897; called by muse, mutect2, varscan2
- SERPINB4 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 121/274 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs140805883; called by muse, mutect2, varscan2
- SERPINB4 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 130/295 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100345349; called by muse, mutect2, varscan2
- SETX | c.3517C>T p.P1173S | Missense Mutation (SNP) | VAF 192/393 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs141996565; called by muse, mutect2, varscan2
- SIGLEC11 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.53); catalogued as rs544419480; called by muse, mutect2, varscan2
- SIGLEC12 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 180/400 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as rs150618212, COSV52464629; called by muse, mutect2, varscan2
- SIGLEC5 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 191/510 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs1207503947; called by muse, mutect2, varscan2
- SLC17A4 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 323/505 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757729766, COSV64957509; called by muse, mutect2, varscan2
- SLC25A24 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 301/620 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs866607066; called by muse, mutect2, varscan2
- SLC44A5 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 134/290 reads (46%) | SIFT tolerated (0.85); PolyPhen benign (0.216); catalogued as COSV63759539, COSV63760252; called by muse, mutect2, varscan2
- SLC5A8 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); catalogued as rs778188770, COSV73311323; called by muse, mutect2
- SMG8 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 186/436 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs970762538; called by muse, mutect2, varscan2
- SMG9 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 178/364 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs775948640, COSV54215466; called by muse, mutect2, varscan2
- SP140 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 93/233 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs765460715, COSV59448176; called by muse, mutect2, varscan2
- SPA17 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 133/133 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs187798202, COSV57031802, COSV57032417, COSV57032607; called by muse, mutect2, varscan2
- SPAG17 | c.3518C>T p.P1173L | Missense Mutation (SNP) | VAF 145/303 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV60463682; called by muse, mutect2, varscan2
- SPATA31D1 | c.2671G>A p.E891K | Missense Mutation (SNP) | VAF 208/465 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.499); catalogued as COSV61193066, COSV61201208; called by muse, mutect2, varscan2
- SPATS2 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 193/346 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773366687, COSV100423462; called by muse, mutect2, varscan2
- SPDYE6 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 179/1105 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as rs1554562299, COSV59504871; called by muse, mutect2, varscan2
- SPHKAP | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 142/328 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60897672; called by muse, varscan2
- SPIDR | c.1912C>T p.L638F | Missense Mutation (SNP) | VAF 158/339 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs761132270; called by muse, mutect2, varscan2
- SPTA1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 93/181 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV63753714; called by muse, mutect2, varscan2
- SRRM4 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 244/493 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV57422964; called by muse, mutect2, varscan2
- SSTR1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 290/596 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs749916089, COSV57457993; called by muse, varscan2
- ST3GAL2 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 237/540 reads (44%) | PolyPhen probably damaging (0.997); catalogued as COSV61595613; called by muse, mutect2, varscan2
- ST8SIA5 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 197/443 reads (44%) | PolyPhen probably damaging (1); catalogued as COSV100164518; called by muse, mutect2, varscan2
- ST8SIA6 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 139/287 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs759600604; called by muse, mutect2, varscan2
- STARD9 | c.9566C>T p.S3189F | Missense Mutation (SNP) | VAF 134/267 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV51909462; called by muse, mutect2, varscan2
- STK4 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs371236375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STYXL2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 243/496 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs776148882, COSV54803377; called by muse, mutect2, varscan2
- SUFU | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 203/404 reads (50%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as rs758001170; called by muse, mutect2, varscan2
- SYNE2 | c.4688C>T p.S1563L | Missense Mutation (SNP) | VAF 106/275 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs748713876, COSV59941406; called by muse, mutect2, varscan2
- SYT10 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 147/272 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267603446; called by muse, mutect2, varscan2
- SYT17 | c.36T>C p.G12= | Splice Region (SNP) | VAF 70/149 reads (47%) | catalogued as rs930752613; called by muse, mutect2, varscan2
- TACC2 | c.5356C>T p.P1786S | Missense Mutation (SNP) | VAF 274/501 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as rs371867918; called by muse, mutect2, varscan2
- TBC1D8B | c.1939C>T p.L647F | Missense Mutation (SNP) | VAF 218/219 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778624354; called by muse, mutect2, varscan2
- TCFL5 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 186/400 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.829); catalogued as rs201056573, COSV53895417; called by muse, mutect2, varscan2
- TDRD15 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 176/362 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1470550466; called by muse, mutect2, varscan2
- TEK | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 197/197 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs771578973, COSV66228520; called by muse, mutect2, varscan2
- TENM4 | c.7222G>A p.D2408N | Missense Mutation (SNP) | VAF 196/453 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as COSV53608601, COSV53656348; called by muse, mutect2, varscan2
- TENM4 | c.1987A>C p.M663L | Missense Mutation (SNP) | VAF 160/328 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99571397; called by muse, mutect2, varscan2
- TENT5C | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 201/423 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65616213; called by muse, mutect2, varscan2
- TF | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 118/240 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as COSV53924691; called by muse, mutect2, varscan2
- TGFBI | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 145/269 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs759370852, COSV59352077, COSV59354114; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THEMIS | c.1585A>G p.R529G | Missense Mutation (SNP) | VAF 227/468 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs755543363; called by muse, mutect2, varscan2
- THOP1 | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 284/593 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.179); catalogued as rs1416001453; called by muse, mutect2, varscan2
- TINAG | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 173/383 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52516310; called by muse, mutect2, varscan2
- TINAG | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 228/458 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs115438249, COSV52508165; called by muse, mutect2, varscan2
- TLN2 | c.6477G>A p.T2159= | Splice Region (SNP) | VAF 115/254 reads (45%) | catalogued as rs921439954; called by muse, mutect2, varscan2
- TLR4 | c.1687G>A p.E563K (on ENST00000355622 / NM_138554.5; = p.E523K on NM_003266.4) | Missense Mutation (SNP) | VAF 143/305 reads (47%) | SIFT tolerated (0.79); PolyPhen benign (0.058); catalogued as COSV62924263; called by muse, mutect2, varscan2
- TMEM156 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 188/367 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs149276693, COSV60745754; called by muse, mutect2, varscan2
- TNC | c.6552G>A p.M2184I | Missense Mutation (SNP) | VAF 163/345 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60780968; called by muse, mutect2, varscan2
- TNNI3K | c.1178-1G>A p.X393_splice | Splice Site (SNP) | VAF 105/227 reads (46%) | catalogued as rs907936579; called by muse, mutect2, varscan2
- TOR4A | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 331/682 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as rs1464273319; called by muse, mutect2, varscan2
- TPTE | c.1340C>T p.S447L (on ENST00000618007 / NM_199261.4; = p.S429L on NM_199259.4) | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs759301774; called by muse, mutect2, varscan2
- TRANK1 | c.7867G>A p.E2623K | Missense Mutation (SNP) | VAF 190/459 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as rs1197024240, COSV57154401; called by muse, mutect2, varscan2
- TRAV4 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 162/372 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs372255405; called by muse, mutect2, varscan2
- TRHDE | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 139/291 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs767303355, COSV53830705; called by muse, mutect2, varscan2
- TRIM64B | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 221/946 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as rs765075149; called by muse, mutect2, varscan2
- TRPM6 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 127/271 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV62506789; called by muse, mutect2, varscan2
- TRPS1 | c.1810C>T p.P604S (on ENST00000220888 / NM_001330599.2; = p.P617S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 181/939 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs369619683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.95951C>T p.P31984L (on ENST00000591111; = p.P24560L on NM_003319.4) | Missense Mutation (SNP) | VAF 163/333 reads (49%) | PolyPhen probably damaging (1); catalogued as COSV100631974; called by muse, mutect2, varscan2
- TTN | c.64631G>A p.R21544Q (on ENST00000591111; = p.R14120Q on NM_003319.4) | Missense Mutation (SNP) | VAF 252/490 reads (51%) | PolyPhen probably damaging (0.996); catalogued as rs201448988; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.57961G>A p.D19321N (on ENST00000591111; = p.D11897N on NM_003319.4) | Missense Mutation (SNP) | VAF 207/454 reads (46%) | PolyPhen benign (0.001); catalogued as COSV100595767; called by muse, mutect2, varscan2
- TTN | c.29854C>T p.P9952S (on ENST00000591111; = p.P9025S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/120 reads (46%) | PolyPhen benign (0.001); catalogued as COSV59916012; called by muse, mutect2, varscan2
- TTN | c.26746G>A p.E8916K (on ENST00000591111; = p.E7989K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 199/413 reads (48%) | PolyPhen possibly damaging (0.54); catalogued as COSV59918127; called by muse, mutect2, varscan2
- TTN | c.13067G>A p.G4356E (on ENST00000591111; = p.G4310E on NM_003319.4) | Missense Mutation (SNP) | VAF 154/330 reads (47%) | catalogued as rs374361492; called by muse, mutect2, varscan2
- UGT1A3 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 203/425 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs143192251; called by muse, mutect2, varscan2
- UGT2A1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54139153; called by muse, mutect2, varscan2
- UGT3A2 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 129/274 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs868312654, COSV56930235; called by muse, mutect2, varscan2
- UHRF1BP1L | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 133/283 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54435893; called by muse, mutect2, varscan2
- USP29 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 105/251 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54140543; called by muse, mutect2, varscan2
- VPS41 | c.1736C>T p.S579L | Missense Mutation (SNP) | VAF 101/242 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV59648355; called by muse, mutect2, varscan2
- WDR97 | c.2611C>T p.R871C | Missense Mutation (SNP) | VAF 209/991 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as rs756021357, COSV100075861; called by muse, mutect2, varscan2
- WDTC1 | c.1720C>T p.R574C (on ENST00000319394 / NM_001276252.2; = p.R573C on NM_015023.5) | Missense Mutation (SNP) | VAF 242/478 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1359642167, COSV99070421; called by muse, mutect2, varscan2
- WFS1 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 278/537 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs371911218, CD993079; called by muse, mutect2, varscan2
- YBX3 | c.264C>T p.A88= | Splice Region (SNP) | VAF 89/207 reads (43%) | catalogued as rs765950938; called by muse, mutect2, varscan2
- ZC4H2 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758832940, COSV62002567; called by muse, mutect2, varscan2
- ZIM2 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 96/196 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV99032385; called by muse, mutect2, varscan2
- ZNF335 | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 148/310 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs754027485; called by muse, mutect2, varscan2
- ZNF34 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 147/823 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV58641336; called by muse, mutect2, varscan2
- ZNF385D | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 205/464 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV55749688; called by muse, mutect2, varscan2
- ZNF420 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 87/173 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV100421552; called by muse, mutect2, varscan2
- ZNF527 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 127/255 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.276); catalogued as COSV62230007; called by muse, mutect2, varscan2
- ZNF665 | c.1234C>T p.R412W (on ENST00000600412; = p.R477W on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 210/470 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.727); catalogued as rs866466787, COSV67213198; called by muse, mutect2, varscan2
- ZNF701 | c.979C>T p.H327Y (on ENST00000301093; = p.H261Y on NM_018260.3) | Missense Mutation (SNP) | VAF 193/413 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1001823737; called by muse, mutect2
- ZNF717 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 152/814 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs1045936818; called by muse, mutect2
- ZSCAN18 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 283/580 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as COSV53738214; called by muse, varscan2
- ZSWIM2 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV54579407; called by muse, mutect2, varscan2
- ABCA12 | c.4865C>T p.P1622L (on ENST00000272895 / NM_173076.3; = p.P1304L on NM_015657.3) | Missense Mutation (SNP) | VAF 176/356 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ABCA5 | c.129del p.L43Ffs*4 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by pindel, varscan2
- ABCB5 | c.491A>C p.N164T | Missense Mutation (SNP) | VAF 148/278 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, varscan2
- ACSM2B | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 156/434 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, varscan2
- ADAMTS20 | c.4192T>A p.C1398S | Missense Mutation (SNP) | VAF 194/382 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTSL5 | c.1229G>A p.W410* | Nonsense Mutation (SNP) | VAF 338/650 reads (52%) | called by muse, mutect2, varscan2
- ADAR | c.2008C>G p.Q670E | Missense Mutation (SNP) | VAF 202/438 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRB1 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 385/1903 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADGRD2 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 195/446 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ADGRF4 | c.206A>C p.D69A | Missense Mutation (SNP) | VAF 168/342 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ADGRG4 | c.4595C>T p.P1532L | Missense Mutation (SNP) | VAF 238/238 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ADGRL2 | c.2690T>C p.F897S (on ENST00000370717 / NM_001366005.1; = p.F884S on NM_012302.4) | Missense Mutation (SNP) | VAF 103/205 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ADGRV1 | c.17522G>A p.R5841K | Missense Mutation (SNP) | VAF 186/374 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AGAP5 | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 291/698 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AGBL1 | c.2955G>A p.M985I | Missense Mutation (SNP) | VAF 140/274 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- AGBL1 | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 138/272 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGRN | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 198/408 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- AGRN | c.4511C>T p.A1504V | Missense Mutation (SNP) | VAF 228/430 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- AGXT2 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 117/260 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AHNAK | c.6265C>T p.P2089S | Missense Mutation (SNP) | VAF 264/520 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- AKAP10 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 128/289 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ANKRD26 | c.2750T>C p.L917S | Missense Mutation (SNP) | VAF 105/228 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ANKRD30A | c.967A>T p.K323* (on ENST00000611781; = p.K267* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 264/572 reads (46%) | called by muse, mutect2, varscan2
- ANKRD33 | c.626C>G p.S209W (on ENST00000340970 / NM_001304459.2; = p.S334W on NM_182608.4) | Missense Mutation (SNP) | VAF 328/656 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- ANO5 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANXA3 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- APLF | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 183/407 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- APOB | c.9181C>T p.P3061S | Missense Mutation (SNP) | VAF 179/379 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARG1 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 160/299 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP11A | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 183/372 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ARHGAP33 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 249/539 reads (46%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP5 | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 172/350 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF1 | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 206/441 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- ARMC4 | c.1269del p.S424Afs*35 | Frame Shift Del (DEL) | VAF 118/373 reads (32%) | called by pindel, varscan2
- ASAH2 | c.1416G>A p.G472= | Splice Region (SNP) | VAF 126/258 reads (49%) | called by muse, mutect2, varscan2
- ASXL2 | c.1649A>T p.N550I | Missense Mutation (SNP) | VAF 167/358 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP10D | c.4061G>A p.G1354E | Missense Mutation (SNP) | VAF 165/384 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP1B3 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 120/246 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP2A3 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 217/217 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP2B1 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 203/405 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- BRAT1 | c.2402C>T p.S801F | Missense Mutation (SNP) | VAF 326/623 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRF2 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 223/452 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- C2 | c.2030G>A p.G677E | Missense Mutation (SNP) | VAF 526/782 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- C3 | c.3161C>T p.T1054I | Missense Mutation (SNP) | VAF 174/353 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CALML5 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 192/394 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CAMTA1 | c.3850C>T p.P1284S | Missense Mutation (SNP) | VAF 211/433 reads (49%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN14 | c.1430T>A p.I477K | Missense Mutation (SNP) | VAF 160/359 reads (45%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC141 | c.2076A>T p.K692N | Missense Mutation (SNP) | VAF 126/271 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- CCDC141 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 160/324 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC150 | c.1816C>A p.L606I | Missense Mutation (SNP) | VAF 131/276 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CCDC180 | c.2419T>C p.F807L | Missense Mutation (SNP) | VAF 223/458 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC88B | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 187/377 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CD163L1 | c.1159C>T p.H387Y | Missense Mutation (SNP) | VAF 187/379 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- CDH23 | c.5929C>T p.P1977S | Missense Mutation (SNP) | VAF 146/301 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH6 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 193/452 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CEP290 | c.1015A>G p.K339E | Missense Mutation (SNP) | VAF 146/288 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- CERT1 | c.1697G>A p.G566E (on ENST00000405807 / NM_001130105.1; = p.G438E on NM_005713.3) | Missense Mutation (SNP) | VAF 160/326 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CERT1 | c.1262A>C p.N421T (on ENST00000405807 / NM_001130105.1; = p.N293T on NM_005713.3) | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CFAP46 | c.1345C>T p.L449F | Missense Mutation (SNP) | VAF 328/668 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); called by muse, mutect2
- CFAP54 | c.589A>T p.N197Y | Missense Mutation (SNP) | VAF 156/303 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHD6 | c.6382C>T p.P2128S | Missense Mutation (SNP) | VAF 201/406 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHST5 | c.622C>G p.P208A | Missense Mutation (SNP) | VAF 287/677 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- CHSY1 | c.1147T>G p.Y383D | Missense Mutation (SNP) | VAF 251/466 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CLDN19 | c.8A>G p.N3S | Missense Mutation (SNP) | VAF 121/280 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CLSTN2 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 124/281 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CMBL | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 194/374 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CNTNAP3 | c.2815G>A p.G939R | Missense Mutation (SNP) | VAF 109/319 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL14A1 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 463/581 reads (80%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A1 | c.2545G>A p.G849R | Missense Mutation (SNP) | VAF 266/522 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A5 | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 176/176 reads (100%) | called by muse, mutect2, varscan2
- CPSF4 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 202/483 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPSF7 | c.572C>T p.S191F (on ENST00000394888 / NM_001136040.4; = p.S234F on NM_024811.4) | Missense Mutation (SNP) | VAF 162/333 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CRADD | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 112/263 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- CRYBG3 | c.2509T>G p.S837A | Missense Mutation (SNP) | VAF 104/220 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSMD1 | c.1747T>A p.F583I (on ENST00000520002; = p.F582I on NM_033225.6) | Missense Mutation (SNP) | VAF 118/226 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- CTAGE8 | c.2068G>A p.G690S | Missense Mutation (SNP) | VAF 108/875 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.499); called by muse, varscan2
- CTTNBP2 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 179/338 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CXCL12 | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 124/285 reads (44%) | called by muse, mutect2, varscan2
- CXCR1 | c.309G>A p.W103* | Nonsense Mutation (SNP) | VAF 248/522 reads (48%) | called by muse, mutect2, varscan2
- CYP2C8 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 136/291 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CYREN | c.275A>T p.H92L | Missense Mutation (SNP) | VAF 218/461 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DAB2IP | c.1080T>G p.C360W (on ENST00000408936; = p.C332W on NM_032552.3) | Missense Mutation (SNP) | VAF 208/433 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCDC2C | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 138/285 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DDX17 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 176/382 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DLC1 | c.2272C>T p.P758S (on ENST00000276297 / NM_001348081.2; = p.P321S on NM_006094.5) | Missense Mutation (SNP) | VAF 259/514 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DLL4 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 240/473 reads (51%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- DNAH5 | c.8330C>T p.T2777I | Missense Mutation (SNP) | VAF 217/416 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- DNAH6 | c.9264G>A p.W3088* | Nonsense Mutation (SNP) | VAF 77/189 reads (41%) | called by muse, mutect2, varscan2
- DNAH7 | c.4090G>A p.G1364R | Missense Mutation (SNP) | VAF 96/215 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEF1G | c.995T>C p.L332P | Missense Mutation (SNP) | VAF 130/297 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEF2 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 215/480 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- EHBP1 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 124/272 reads (46%) | called by muse, mutect2, varscan2
- EIF4A1 | c.505A>G p.R169G | Missense Mutation (SNP) | VAF 132/133 reads (99%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPC1 | c.1261G>A p.G421S | Missense Mutation (SNP) | VAF 152/302 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- EPHA10 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 150/344 reads (44%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ERVV-1 | c.1329G>A p.W443* | Nonsense Mutation (SNP) | VAF 177/578 reads (31%) | called by muse, varscan2
- ESPN | c.3030G>A p.W1010* | Nonsense Mutation (SNP) | VAF 342/688 reads (50%) | called by muse, mutect2, varscan2
- ESPN | c.3031G>A p.E1011K | Missense Mutation (SNP) | VAF 343/698 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- FAM20B | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 172/356 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FAM71B | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 275/548 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM83H | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 373/1919 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT4 | c.10633C>T p.P3545S | Missense Mutation (SNP) | VAF 196/377 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCN3 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 134/295 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- FCRL5 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 219/434 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGD5 | c.3265-1G>A p.X1089_splice | Splice Site (SNP) | VAF 196/403 reads (49%) | called by muse, mutect2, varscan2
- FLT1 | c.821A>G p.K274R | Missense Mutation (SNP) | VAF 109/246 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FOS | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 217/428 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FRAS1 | c.11494C>T p.P3832S | Missense Mutation (SNP) | VAF 172/324 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FREM2 | c.7753G>A p.D2585N | Missense Mutation (SNP) | VAF 204/449 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- FUT9 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 181/182 reads (99%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FYB2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 157/371 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- GAGE10 | c.250G>C p.G84R | Missense Mutation (SNP) | VAF 77/78 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- GALNT13 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 116/216 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- GALNT16 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 139/297 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- GLI2 | c.2453C>T p.S818F (on ENST00000361492 / NM_001374353.1; = p.S835F on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 380/792 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GLRX5 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 302/612 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GRAMD2A | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 141/311 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- GRAMD2A | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 140/310 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- GRWD1 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 249/566 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- GSDMC | c.1452G>A p.W484* | Nonsense Mutation (SNP) | VAF 796/999 reads (80%) | called by muse, mutect2, varscan2
- H1-7 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 310/620 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- HAS1 | c.705C>T p.V235= | Splice Region (SNP) | VAF 110/232 reads (47%) | called by muse, mutect2, varscan2
- HECTD4 | c.1588G>A p.G530S | Missense Mutation (SNP) | VAF 189/397 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECW2 | c.3529G>A p.G1177S | Missense Mutation (SNP) | VAF 94/192 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HEPHL1 | c.2565G>A p.M855I | Missense Mutation (SNP) | VAF 115/242 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN1 | c.12187C>T p.P4063S | Missense Mutation (SNP) | VAF 137/324 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- HMMR | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 103/201 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- HOMEZ | c.1105G>C p.A369P | Missense Mutation (SNP) | VAF 267/514 reads (52%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HOXA4 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 288/635 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- HPSE2 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 212/444 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HRH1 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 245/474 reads (52%) | SIFT tolerated (0.75); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HSPA1L | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 482/742 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- HYDIN | c.14134C>T p.P4712S | Missense Mutation (SNP) | VAF 84/219 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFT122 | c.3614C>T p.T1205I (on ENST00000348417 / NM_052989.3; = p.T1146I on NM_018262.4) | Missense Mutation (SNP) | VAF 200/409 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IFT52 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 197/462 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- IGHV3-16 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 310/648 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- IGSF1 | c.1538G>A p.W513* | Nonsense Mutation (SNP) | VAF 142/142 reads (100%) | called by muse, mutect2, varscan2
- IGSF21 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 133/271 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL18RAP | c.143T>A p.L48* | Nonsense Mutation (SNP) | VAF 178/352 reads (51%) | called by muse, mutect2, varscan2
- IL23R | c.826T>G p.Y276D | Missense Mutation (SNP) | VAF 147/306 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- IQCM | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 209/428 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, varscan2
- IQCN | c.2713G>A p.A905T | Missense Mutation (SNP) | VAF 301/636 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- IRX4 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 315/660 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ITGA8 | c.1608A>G p.I536M | Missense Mutation (SNP) | VAF 147/279 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- ITK | c.1493T>G p.V498G | Missense Mutation (SNP) | VAF 158/358 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ITPR1 | c.2362C>T p.H788Y (on ENST00000354582; = p.H773Y on NM_002222.7) | Missense Mutation (SNP) | VAF 278/537 reads (52%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPR1 | c.5422G>A p.V1808I (on ENST00000354582; = p.V1753I on NM_002222.7) | Missense Mutation (SNP) | VAF 214/469 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IZUMO2 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 189/402 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- JAKMIP3 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 294/591 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- JCAD | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 199/406 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- KCNA4 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 269/514 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCND2 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 132/253 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ12 | c.124T>C p.C42R | Missense Mutation (SNP) | VAF 264/843 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNK10 | c.268T>A p.F90I | Missense Mutation (SNP) | VAF 264/554 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1217 | c.1433T>C p.V478A | Missense Mutation (SNP) | VAF 222/429 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- KIAA1217 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 159/336 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- KIAA1217 | c.5381C>T p.S1794F | Missense Mutation (SNP) | VAF 190/431 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KIF4B | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 240/523 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- KMT2C | c.4610C>T p.P1537L | Missense Mutation (SNP) | VAF 152/303 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- KRT6C | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 273/609 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- LACTBL1 | c.8C>T p.P3L (on ENST00000618559; = p.P32L on NM_001289974.2) | Missense Mutation (SNP) | VAF 186/426 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LACTBL1 | c.7C>T p.P3S (on ENST00000618559; = p.P32S on NM_001289974.2) | Missense Mutation (SNP) | VAF 185/424 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA2 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LAMA2 | c.4189G>A p.G1397R | Missense Mutation (SNP) | VAF 140/140 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGR6 | c.677G>A p.G226E (on ENST00000367278 / NM_001017403.1; = p.G174E on NM_021636.3) | Missense Mutation (SNP) | VAF 186/371 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LHCGR | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 191/356 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LHX5 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 207/483 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- LIMCH1 | c.2581G>A p.G861R | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- LPIN1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 104/252 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC8E | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 190/409 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRSAM1 | c.1111T>C p.S371P | Missense Mutation (SNP) | VAF 177/339 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- MAGEC1 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 273/279 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- MALRD1 | c.2482C>T p.H828Y | Missense Mutation (SNP) | VAF 180/408 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MAOB | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 204/204 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPK8IP3 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 260/557 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCOL | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 218/448 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MAST3 | c.2491C>T p.L831F | Missense Mutation (SNP) | VAF 259/473 reads (55%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- MCHR2 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 277/277 reads (100%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- ME1 | c.418T>A p.W140R | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by mutect2, varscan2
- MECOM | c.947C>T p.P316L (on ENST00000468789 / NM_001105078.4; = p.P504L on NM_004991.4) | Missense Mutation (SNP) | VAF 191/412 reads (46%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MGAM2 | c.2668G>A p.D890N | Missense Mutation (SNP) | VAF 124/256 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MGAM2 | c.3653T>G p.L1218W | Missense Mutation (SNP) | VAF 148/370 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMP13 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 127/127 reads (100%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MMRN1 | c.2504G>A p.R835K | Missense Mutation (SNP) | VAF 129/302 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- MST1R | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 283/571 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTMR4 | c.1450T>C p.F484L | Missense Mutation (SNP) | VAF 131/263 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- MUC12 | c.15955G>A p.D5319N (on ENST00000379442; = p.D5176N on NM_001164462.1) | Missense Mutation (SNP) | VAF 176/333 reads (53%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MUC16 | c.13601C>T p.S4534F | Missense Mutation (SNP) | VAF 138/301 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- MUC16 | c.13072C>T p.Q4358* | Nonsense Mutation (SNP) | VAF 144/307 reads (47%) | called by muse, mutect2, varscan2
- MUC17 | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 235/492 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- MUC20 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 167/689 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MUC4 | c.7316C>T p.S2439F | Missense Mutation (SNP) | VAF 293/1336 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); called by muse, varscan2
- MYB | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYOM2 | c.3580G>A p.D1194N | Missense Mutation (SNP) | VAF 125/325 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MYRFL | c.2495G>A p.G832E | Missense Mutation (SNP) | VAF 111/228 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBEAL2 | c.5495C>T p.A1832V | Missense Mutation (SNP) | VAF 171/388 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- NCKAP1L | c.2070G>A p.M690I | Missense Mutation (SNP) | VAF 135/305 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEBL | c.2717G>A p.S906N | Missense Mutation (SNP) | VAF 137/311 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NEFH | c.1465G>A p.G489S | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEFM | c.2714C>T p.S905L | Missense Mutation (SNP) | VAF 118/250 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- NF2 | c.888_912del p.I296Mfs*5 | Frame Shift Del (DEL) | VAF 67/70 reads (96%) | called by mutect2, pindel, varscan2
- NIPAL3 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 209/409 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NMT1 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 168/359 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- NOTCH1 | c.2167A>G p.N723D | Missense Mutation (SNP) | VAF 297/577 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NPY5R | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 148/300 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NRROS | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 210/442 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- NYX | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 355/355 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- OAZ1 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 232/497 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- OPN5 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 182/390 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR10R2 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 198/392 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.11); called by muse, mutect2
- OR14A2 | c.885G>A p.M295I | Missense Mutation (SNP) | VAF 163/351 reads (46%) | SIFT tolerated (0.88); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR1L3 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 179/404 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR2AP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 104/201 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR4X1 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 231/491 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OR51I1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 109/235 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5D16 | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 185/390 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- OR7C2 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 140/295 reads (47%) | called by muse, mutect2, varscan2
- OR8D1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 215/215 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OVCH2 | c.425A>G p.D142G | Missense Mutation (SNP) | VAF 133/306 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PACSIN1 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 199/652 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PAK5 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 189/374 reads (51%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHA11 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 263/573 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PCDHGA10 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 156/336 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCLO | c.7766C>T p.P2589L | Missense Mutation (SNP) | VAF 188/352 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- PCLO | c.5512C>T p.P1838S | Missense Mutation (SNP) | VAF 177/362 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- PCLO | c.4580G>A p.R1527K | Missense Mutation (SNP) | VAF 179/374 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- PDE1C | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 182/403 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PDGFRB | c.446G>A p.C149Y | Missense Mutation (SNP) | VAF 228/487 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PFKFB1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 199/199 reads (100%) | PolyPhen benign (0.445); called by muse, mutect2, varscan2
- PGLYRP4 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 150/308 reads (49%) | called by muse, mutect2, varscan2
- PIM3 | c.547G>T p.G183* | Nonsense Mutation (SNP) | VAF 167/351 reads (48%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.6865G>A p.D2289N | Missense Mutation (SNP) | VAF 570/728 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PLEKHO1 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 245/488 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PLG | c.674C>A p.P225Q | Missense Mutation (SNP) | VAF 130/375 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLPPR5 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 150/292 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PLXNC1 | c.5_6del p.E2Gfs*185 | Frame Shift Del (DEL) | VAF 144/381 reads (38%) | called by mutect2, pindel, varscan2
- PPFIA2 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 180/413 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PPP2R3A | c.3379A>T p.N1127Y | Missense Mutation (SNP) | VAF 93/206 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- PPP4R3C | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 141/141 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PPP6R1 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 174/368 reads (47%) | called by muse, mutect2, varscan2
- PRKCQ | c.790+1G>A p.X264_splice | Splice Site (SNP) | VAF 169/323 reads (52%) | called by muse, mutect2, varscan2
- PROS1 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 167/355 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRUNE2 | c.5150G>A p.W1717* | Nonsense Mutation (SNP) | VAF 170/392 reads (43%) | called by muse, mutect2
- PRUNE2 | c.2353C>T p.P785S | Missense Mutation (SNP) | VAF 248/467 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PSG8 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 207/459 reads (45%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRD | c.2773C>T p.L925F | Missense Mutation (SNP) | VAF 238/238 reads (100%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PUM1 | c.3196C>T p.R1066* | Nonsense Mutation (SNP) | VAF 171/358 reads (48%) | called by muse, mutect2, varscan2
- RAB19 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 227/450 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAI14 | c.2881G>T p.D961Y | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- RFFL | c.407A>T p.Q136L | Missense Mutation (SNP) | VAF 251/515 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- RFPL4A | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 101/928 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); called by muse, mutect2
- RFPL4AL1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 90/519 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- RGPD4 | c.3908C>T p.S1303F | Missense Mutation (SNP) | VAF 181/432 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RGPD4 | c.4733T>C p.L1578S | Missense Mutation (SNP) | VAF 183/405 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- RGS4 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 221/462 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RHBDL3 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 175/360 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- RIT1 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 220/506 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2
- RIT1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 222/505 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.045); called by muse, mutect2
- RNF6 | c.1596C>G p.H532Q | Missense Mutation (SNP) | VAF 202/361 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ROBO4 | c.2779G>A p.D927N | Missense Mutation (SNP) | VAF 139/139 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ROS1 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RP1 | c.1124G>T p.S375I | Missense Mutation (SNP) | VAF 135/283 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- RPS27AP5 | c.191A>T p.E64V | Missense Mutation (SNP) | VAF 234/496 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RYR1 | c.5582A>C p.Q1861P | Missense Mutation (SNP) | VAF 221/422 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- SARM1 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 380/729 reads (52%) | called by muse, mutect2, varscan2
- SCAI | c.206C>T p.S69F (on ENST00000336505 / NM_001144877.3; = p.S92F on NM_173690.5) | Missense Mutation (SNP) | VAF 109/225 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SCART1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 241/518 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SCN3A | c.5365G>A p.D1789N | Missense Mutation (SNP) | VAF 226/482 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCNM1 | c.589del p.R197Efs*14 | Frame Shift Del (DEL) | VAF 132/351 reads (38%) | called by mutect2, pindel, varscan2
- SEC31A | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 156/328 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SFSWAP | c.408G>T p.L136F | Missense Mutation (SNP) | VAF 135/298 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SIGLEC9 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 136/284 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SINHCAF | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 176/397 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- SLC16A14 | c.1232T>C p.I411T | Missense Mutation (SNP) | VAF 181/361 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, varscan2
- SLC1A4 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 149/310 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- SLC1A6 | c.1045G>A p.G349S | Missense Mutation (SNP) | VAF 192/421 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- SLC22A11 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 270/581 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC24A3 | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 131/267 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC38A3 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 271/522 reads (52%) | SIFT tolerated (0.54); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- SLC39A11 | c.692G>A p.R231K (on ENST00000542342 / NM_001159770.2; = p.R224K on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 137/289 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC46A1 | c.548T>A p.L183Q | Missense Mutation (SNP) | VAF 360/663 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- SLC6A5 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 335/661 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLCO2A1 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 163/339 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMIM24 | c.364C>A p.H122N | Missense Mutation (SNP) | VAF 203/396 reads (51%) | SIFT tolerated (0.89); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SNCAIP | c.2240G>A p.S747N | Missense Mutation (SNP) | VAF 179/371 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SOS1 | c.3192T>G p.S1064R | Missense Mutation (SNP) | VAF 137/280 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SPAG17 | c.3517C>T p.P1173S | Missense Mutation (SNP) | VAF 148/305 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- SPANXN3 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 272/272 reads (100%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SPARC | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 175/364 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SPATA31A7 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT deleterious (0.02); PolyPhen benign (0.263); called by mutect2, varscan2
- SPECC1 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 213/480 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- SPEM3 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 195/195 reads (100%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ST8SIA3 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 142/316 reads (45%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STK33 | c.901A>G p.S301G | Missense Mutation (SNP) | VAF 143/297 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- STON2 | c.958C>T p.P320S (on ENST00000649389 / NM_001366849.2; = p.P263S on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/385 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SULT6B1 | c.566G>A p.W189* (on ENST00000535679 / NM_001367551.1; = p.W151* on NM_001032377.2) | Nonsense Mutation (SNP) | VAF 116/249 reads (47%) | called by muse, mutect2, varscan2
- SYNE2 | c.8866C>T p.Q2956* | Nonsense Mutation (SNP) | VAF 146/304 reads (48%) | called by muse, mutect2, varscan2
- TAB1 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 269/559 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TC2N | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 134/297 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- TESMIN | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 253/503 reads (50%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TEX35 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 236/469 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TFAP2A | c.220C>T p.P74S (on ENST00000482890; = p.P66S on NM_001032280.3) | Missense Mutation (SNP) | VAF 145/403 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TMEM163 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 133/281 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TNS1 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 291/636 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TOX2 | c.909C>T p.S303= (on ENST00000358131 / NM_001098798.2; = p.S279= on NM_032883.3) | Splice Region (SNP) | VAF 171/349 reads (49%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 218/1099 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TRAV22 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 106/219 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRIM3 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 325/663 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TRPC4 | c.2075T>C p.I692T | Missense Mutation (SNP) | VAF 105/225 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- TSPAN15 | c.702G>A p.M234I | Missense Mutation (SNP) | VAF 205/424 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- TTC28 | c.5378A>C p.D1793A | Missense Mutation (SNP) | VAF 431/745 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- TTN | c.79166T>G p.V26389G (on ENST00000591111; = p.V18965G on NM_003319.4) | Missense Mutation (SNP) | VAF 174/381 reads (46%) | PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TTN | c.45575G>C p.G15192A (on ENST00000591111; = p.G7768A on NM_003319.4) | Missense Mutation (SNP) | VAF 212/482 reads (44%) | PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
488 further variants in this file (33 protein-altering or splice-affecting, 412 silent, 43 other) are not listed here.
